Somatic mutation profile of tumor specimen TCGA-IR-A3LA-01A (aliquot TCGA-IR-A3LA-01A-11D-A22X-09) from TCGA case TCGA-IR-A3LA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 60.1 years (21,949 days).
Specimen TCGA-IR-A3LA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3694dfd4-30c5-4479-816d-a1479ae4612d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IR-A3LA-10A (Blood Derived Normal), aliquot TCGA-IR-A3LA-10A-01D-A22X-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f30894f7-cb9b-44ff-bbe6-6c098fcd8810

The open-access MAF lists 1,199 somatic variants for this specimen: 849 protein-altering or splice-affecting, 315 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 745, Silent 315, Nonsense Mutation 76, Intron 13, Splice Site 10, Splice Region 8, RNA 7, 3'UTR 5, 5'UTR 4, Nonstop Mutation 4, 5'Flank 4, Frame Shift Del 3.

Variants (750 of 1,199; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.6475C>T p.Q2159* | Nonsense Mutation (SNP) | VAF 10/19 reads (53%) | catalogued as rs398122558, COSV66453014, COSV66458696; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 36/86 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GCK | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1554335566, CM096832, COSV60786479; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 29/36 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060501191, COSV52666332, COSV52700326, COSV52746468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 24/47 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780071, CM120848, COSV52677226, COSV52796536, COSV53623808; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV62789820; called by muse, mutect2, varscan2
- ABCA13 | c.12962C>T p.S4321L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as COSV68946248; called by muse, mutect2, varscan2
- ABCA4 | c.3326C>G p.S1109* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV64673225; called by muse, varscan2
- ABCA4 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as CM161622, COSV64673228, COSV64674391; called by muse, mutect2, varscan2
- ABCB1 | c.3662C>G p.A1221G | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55950221; called by muse, mutect2, varscan2
- ABCC3 | c.4486C>G p.L1496V | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV53321107; called by muse, mutect2, varscan2
- AC004922.1 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV53556640; called by muse, mutect2, varscan2
- AC024598.1 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.027); catalogued as COSV60823987; called by muse, mutect2, varscan2
- AC126283.2 | c.1370C>G p.S457C | Missense Mutation (SNP) | VAF 60/98 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101144352; called by muse, mutect2, varscan2
- ACAN | c.7309G>C p.E2437Q (on ENST00000560601 / NM_001369268.1; = p.E2361Q on NM_001135.3) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61359783, COSV61368709; called by muse, mutect2, varscan2
- ACTG2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.916); catalogued as COSV61828237; called by muse, mutect2, varscan2
- ACTR8 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.143); catalogued as COSV51636152; called by muse, mutect2, varscan2
- ADAM21 | c.1050G>T p.Q350H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.021); catalogued as COSV50792060; called by muse, mutect2, varscan2
- ADAM21 | c.1805C>G p.S602C | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1371544056, COSV50792092, COSV50792242; called by muse, mutect2, varscan2
- ADAM7 | c.234-1G>A p.X78_splice | Splice Site (SNP) | VAF 22/33 reads (67%) | catalogued as COSV51539269; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3688G>A p.D1230N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.751); catalogued as rs1383691398, COSV54446158; called by muse, mutect2, varscan2
- ADAMTSL4 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV54999328; called by muse, mutect2, varscan2
- ADCY10 | c.1990C>G p.L664V | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63240478; called by muse, mutect2
- ADGRA1 | c.335G>C p.W112S | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV101658599; called by muse, mutect2, varscan2
- ADGRB3 | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65393310; called by muse, mutect2, varscan2
- ADGRB3 | c.3056G>A p.G1019E | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53242869; called by muse, mutect2, varscan2
- ADGRF1 | c.2713C>T p.Q905* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV51945265, COSV51948248; called by muse, mutect2, varscan2
- ADGRG4 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 45/73 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV54955138; called by muse, mutect2, varscan2
- ADGRV1 | c.6414C>G p.I2138M | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV101316413, COSV67984327; called by muse, mutect2, varscan2
- AGRN | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.434); catalogued as COSV65069309; called by muse, mutect2, varscan2
- AK6 | c.518G>C p.*173Sext*7 | Nonstop Mutation (SNP) | VAF 21/50 reads (42%) | catalogued as COSV66458712; called by muse, mutect2, varscan2
- AK8 | c.547C>G p.Q183E | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV53753849; called by muse, mutect2, varscan2
- AKAP12 | c.2527G>A p.V843I | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs753654154, COSV53574333; called by muse, mutect2, varscan2
- AKAP13 | c.756C>G p.I252M | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1389258084, COSV63455427; called by muse, mutect2, varscan2
- AKAP6 | c.4468G>C p.E1490Q | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV55212497; called by muse, mutect2, varscan2
- AMER3 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58466480, COSV58466498; called by muse, mutect2, varscan2
- ANK2 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1474105619, COSV52152842; called by muse, mutect2, varscan2
- ANK3 | c.2542G>C p.D848H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55056062; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV51846046; called by muse, mutect2, varscan2
- ANKRD54 | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776362092, COSV53236233; called by muse, mutect2, varscan2
- ANKRD55 | c.246G>C p.K82N | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61946426; called by muse, mutect2, varscan2
- ANO6 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57660496, COSV57664498; called by muse, mutect2, varscan2
- ANXA13 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs201946511, COSV51623022; called by muse, mutect2, varscan2
- ANXA3 | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV53714007; called by muse, mutect2, varscan2
- AOAH | c.977G>C p.R326T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51735971, COSV99333693; called by muse, mutect2, varscan2
- AOPEP | c.79G>C p.V27L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as COSV52917483; called by muse, mutect2, varscan2
- AP3M1 | c.764G>C p.G255A | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62331224; called by muse, mutect2, varscan2
- AP3S2 | c.24C>G p.F8L | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV60518217; called by muse, mutect2, varscan2
- AP4S1 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs183487893, COSV53554548; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APBB1IP | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.195); catalogued as COSV63301720, COSV63301822; called by muse, mutect2, varscan2
- APOB | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.892); catalogued as rs1237885120, COSV51933934; called by muse, mutect2, varscan2
- APOF | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.663); catalogued as COSV58475247; called by muse, mutect2, varscan2
- AQP7 | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 47/130 reads (36%) | catalogued as COSV53012625, COSV53014446; called by muse, mutect2, varscan2
- ARHGEF11 | c.1717G>C p.E573Q | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59354176; called by muse, mutect2, varscan2
- ARHGEF2 | c.143C>G p.S48* (on ENST00000361247 / NM_001162383.2; = p.S21* on NM_004723.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 42/91 reads (46%) | catalogued as COSV100560448, COSV58115336; called by muse, mutect2, varscan2
- ARID1A | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100251522, COSV61376694; called by muse, mutect2, varscan2
- ARID4A | c.3763G>C p.E1255Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62162471; called by muse, mutect2, varscan2
- ARID4B | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51602528; called by muse, mutect2, varscan2
- ARID5B | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV54419507, COSV54427165; called by muse, mutect2, varscan2
- ARL16 | c.468C>G p.I156M | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.074); catalogued as COSV61267759; called by muse, mutect2, varscan2
- ARL6IP5 | c.15C>G p.I5M | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.275); catalogued as rs1320661622, COSV56234953; called by muse, mutect2, varscan2
- ARMCX5 | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV55766499; called by muse, mutect2, varscan2
- ASB2 | c.696G>C p.Q232H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60110458; called by muse, mutect2, varscan2
- ASPM | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV54129115, COSV54132798; called by muse, mutect2, varscan2
- ASTN1 | c.974C>G p.S325C | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.717); catalogued as COSV56067941; called by muse, mutect2, varscan2
- ATE1 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV56435802, COSV99816676; called by muse, mutect2, varscan2
- ATM | c.7256G>C p.R2419T | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV53741346; called by muse, mutect2, varscan2
- ATP13A4 | c.455C>G p.S152C | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV55069006; called by muse, mutect2
- ATRX | c.4560G>C p.V1520= | Splice Region (SNP) | VAF 74/129 reads (57%) | catalogued as COSV64875900; called by muse, mutect2, varscan2
- ATRX | c.2075C>T p.S692L | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100971576, COSV64870948; called by muse, mutect2, varscan2
- AXDND1 | c.2926G>A p.E976K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV62642144; called by muse, mutect2, varscan2
- B4GALNT3 | c.1627C>G p.Q543E | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56752001; called by muse, mutect2, varscan2
- BABAM2 | c.105G>C p.L35F | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV56221667; called by muse, mutect2, varscan2
- BAHCC1 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV100311501; called by muse, mutect2, varscan2
- BARX1 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV54158945; called by muse, mutect2, varscan2
- BAZ2B | c.6238G>T p.E2080* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV58599859; called by muse, mutect2, varscan2
- BBS9 | c.593C>G p.S198C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV54166242; called by muse, mutect2, varscan2
- BCL3 | c.1263C>G p.F421L | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99378089; called by mutect2, varscan2
- BDP1 | c.4102G>C p.E1368Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV62431076; called by muse, mutect2, varscan2
- BEND7 | c.633G>C p.E211D | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.145); catalogued as COSV61988740; called by muse, mutect2, varscan2
- BHMT | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757263273, COSV57154280, COSV99165375; called by muse, mutect2, varscan2
- BMPR1A | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.246); catalogued as COSV64405872; called by muse, mutect2, varscan2
- BMS1 | c.2242G>C p.E748Q | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV65733774; called by muse, mutect2, varscan2
- BRF2 | c.247C>A p.L83M | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV55103384; called by muse, mutect2, varscan2
- BSG | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as rs747110729, COSV61076876, COSV61078309; called by muse, mutect2
- BST1 | c.26C>G p.S9W | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as rs752630803, COSV53946547; called by muse, mutect2
- C20orf194 | c.3472G>C p.E1158Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52695282; called by muse, mutect2, varscan2
- C2CD6 | c.1106C>G p.S369C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.79); catalogued as COSV53794282; called by muse, mutect2, varscan2
- C2orf15 | c.38C>G p.S13C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.943); catalogued as COSV56781778; called by muse, mutect2, varscan2
- CAB39L | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV61714746; called by muse, mutect2, varscan2
- CACNA1I | c.3582C>G p.I1194M | Missense Mutation (SNP) | VAF 66/100 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV60803972, COSV60807173; called by muse, mutect2, varscan2
- CADPS | c.327G>C p.Q109H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV51877840; called by muse, mutect2, varscan2
- CALB2 | c.180G>C p.K60N | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.43); PolyPhen benign (0.222); catalogued as COSV56938660; called by muse, mutect2, varscan2
- CALCRL | c.635G>T p.C212F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66474687; called by muse, mutect2, varscan2
- CAMK1 | c.948G>A p.M316I | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as rs781010077, COSV99844711; called by mutect2, varscan2
- CAMKK2 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV61214499; called by muse, mutect2, varscan2
- CAMSAP3 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV50333729, COSV50364595; called by muse, mutect2, varscan2
- CAMTA1 | c.1887G>C p.Q629H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.556); catalogued as COSV57896676; called by muse, varscan2
- CAPZB | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs377121153; called by muse, mutect2, varscan2
- CASP14 | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55665395; called by muse, mutect2, varscan2
- CASP5 | c.800A>G p.H267R | Missense Mutation (SNP) | VAF 56/75 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52828393; called by muse, mutect2, varscan2
- CATSPERB | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.218); catalogued as COSV56425898, COSV56432368; called by muse, mutect2, varscan2
- CCDC117 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.776); catalogued as COSV50770746; called by muse, mutect2, varscan2
- CCDC141 | c.3346G>C p.E1116Q | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as COSV55372857; called by muse, mutect2, varscan2
- CCDC150 | c.3133G>C p.E1045Q | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV55873970; called by muse, mutect2, varscan2
- CCDC158 | c.396C>G p.I132M | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV66355778; called by muse, mutect2, varscan2
- CCDC186 | c.1522C>G p.L508V | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65161133; called by muse, mutect2, varscan2
- CCDC27 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as rs760910706, COSV53898240; called by muse, mutect2, varscan2
- CCDC39 | c.95C>G p.S32* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV56483266; called by muse, mutect2, varscan2
- CCDC77 | c.297G>C p.Q99H | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV53472824; called by muse, mutect2, varscan2
- CCDC87 | c.2032C>A p.L678M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as COSV59578910; called by muse, varscan2
- CCDC87 | c.1991G>C p.G664A | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as COSV59578912; called by muse, varscan2
- CCT8 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54503848; called by muse, mutect2, varscan2
- CD109 | c.1667A>G p.K556R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV54648866; called by muse, mutect2, varscan2
- CD1E | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 39/84 reads (46%) | catalogued as rs953777542, COSV63770870, COSV63772747; called by muse, mutect2, varscan2
- CD2AP | c.1810C>G p.H604D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV63760562, COSV63761931; called by muse, mutect2
- CD44 | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs371026548; called by muse, mutect2, varscan2
- CDC42BPG | c.4230C>A p.F1410L | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV61347115; called by muse, mutect2, varscan2
- CDH18 | c.2357C>T p.S786F | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV56919125; called by muse, mutect2, varscan2
- CDK11B | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.985); catalogued as rs761815656, COSV52361232; called by muse, mutect2, varscan2
- CDK13 | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51699338; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1423C>G p.Q475E | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV62573958; called by muse, mutect2, varscan2
- CDK8 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs933264029, COSV67420475; called by muse, mutect2, varscan2
- CENPK | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs147863579, COSV99669565; called by muse, mutect2, varscan2
- CEP164 | c.2809G>C p.D937H | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV54040725; called by muse, mutect2, varscan2
- CEP95 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73609069; called by muse, mutect2, varscan2
- CERCAM | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65710866; called by muse, mutect2, varscan2
- CES1 | c.1260G>C p.L420F (on ENST00000361503 / NM_001025194.2; = p.L419F on NM_001266.5) | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as COSV62085290, COSV62086715; called by muse, mutect2, varscan2
- CFAP65 | c.407G>A p.R136K (on ENST00000341552 / NM_194302.4; = p.R71K on NM_152389.4) | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55390226, COSV55390960; called by muse, mutect2, varscan2
- CFAP74 | c.1582G>C p.D528H | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV54567255; called by muse, mutect2, varscan2
- CHD6 | c.2461C>A p.Q821K | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV100498065; called by muse, mutect2
- CHD8 | c.2269G>T p.E757* (on ENST00000646647 / NM_001170629.2; = p.E478* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | catalogued as rs1555315854, COSV101303110, COSV67869484, COSV67872487; called by muse, varscan2
- CHD9 | c.3847C>G p.Q1283E | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54609966; called by muse, mutect2
- CHL1 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV56585273; called by muse, mutect2, varscan2
- CHMP6 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs769881954, COSV57327358; called by muse, mutect2, varscan2
- CHRM2 | c.654G>C p.K218N | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV100280725, COSV57771026; called by muse, mutect2, varscan2
- CHRNB3 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV51494721; called by muse, mutect2, varscan2
- CHST5 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV100292018, COSV60338899; called by muse, mutect2, varscan2
- CIBAR2 | c.639G>C p.E213D | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.22); PolyPhen benign (0.268); catalogued as COSV73320594; called by muse, mutect2, varscan2
- CIDEB | c.482C>G p.S161C | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV51865625; called by muse, mutect2, varscan2
- CLSTN2 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV71720598; called by muse, mutect2, varscan2
- CLSTN3 | c.1303T>C p.F435L | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56935971; called by muse, mutect2, varscan2
- CLTCL1 | c.572C>G p.S191* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV54229561; called by muse, mutect2, varscan2
- CMIP | c.925C>T p.Q309* (on ENST00000537098 / NM_198390.2; = p.Q215* on NM_030629.3) | Nonsense Mutation (SNP) | VAF 20/29 reads (69%) | catalogued as COSV67698083; called by muse, mutect2, varscan2
- CNTN5 | c.107G>C p.R36T | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as rs202004805, COSV54300473; called by muse, mutect2, varscan2
- CNTRL | c.3970G>A p.E1324K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53046501; called by muse, mutect2, varscan2
- COG4 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV56787277; called by muse, mutect2, varscan2
- COL11A1 | c.4897G>A p.D1633N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1303443553, COSV62182158; called by muse, mutect2, varscan2
- COL24A1 | c.2922+1G>T p.X974_splice | Splice Site (SNP) | VAF 19/34 reads (56%) | catalogued as COSV65305574; called by muse, mutect2, varscan2
- COL4A3 | c.3437G>C p.G1146A | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV59257970; called by muse, mutect2, varscan2
- COL9A3 | c.1465C>T p.Q489* | Nonsense Mutation (SNP) | VAF 45/70 reads (64%) | catalogued as COSV58984712, COSV58986910; called by muse, mutect2, varscan2
- COQ8A | c.1143G>C p.M381I | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV64657297; called by muse, mutect2, varscan2
- CPEB3 | c.1953C>G p.F651L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV99799192; called by muse, varscan2
- CPEB4 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV54171495; called by muse, mutect2, varscan2
- CPQ | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV55144614; called by muse, mutect2, varscan2
- CPS1 | c.3998G>C p.G1333A | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM114386, COSV99242744; called by muse, mutect2, varscan2
- CPSF1 | c.675G>C p.Q225H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV62940047; called by muse, mutect2, varscan2
- CPT1A | c.812G>C p.R271T | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV55755520, COSV55758221; called by muse, mutect2, varscan2
- CREG2 | c.442-1G>C p.X148_splice | Splice Site (SNP) | VAF 20/43 reads (47%) | catalogued as COSV61316620; called by muse, mutect2, varscan2
- CRNN | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.494); catalogued as rs773979208, COSV55121771; called by muse, mutect2, varscan2
- CROCC | c.2286G>T p.L762= | Splice Region (SNP) | VAF 8/67 reads (12%) | catalogued as COSV65011807; called by muse, mutect2, varscan2
- CRTC1 | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58718434; called by muse, mutect2, varscan2
- CSAD | c.1222G>T p.E408* (on ENST00000444623 / NM_001244705.2; = p.E435* on NM_015989.5) | Nonsense Mutation (SNP) | VAF 21/47 reads (45%) | catalogued as COSV57242471; called by muse, mutect2, varscan2
- CSF3R | c.2098G>C p.E700Q | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV58966299; called by muse, mutect2, varscan2
- CSMD3 | c.3128G>A p.S1043N (on ENST00000297405 / NM_001363185.1; = p.S939N on NM_052900.3) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV52167731; called by muse, mutect2, varscan2
- CSTF2T | c.38G>C p.R13P | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58656354; called by muse, mutect2, varscan2
- CTNNB1 | c.1937C>G p.S646C | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as rs755119590, COSV62690545, COSV62698719; called by muse, mutect2, varscan2
- CUBN | c.6550C>G p.L2184V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.249); catalogued as rs757157310, COSV64714722; called by muse, mutect2, varscan2
- CYP39A1 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.749); catalogued as COSV51495224; called by muse, mutect2, varscan2
- CYP4F12 | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV61173559; called by muse, mutect2, varscan2
- CYTIP | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV51633524; called by muse, mutect2, varscan2
- DAAM1 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62836003; called by muse, mutect2, varscan2
- DACH2 | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.039); catalogued as COSV64167677, COSV64188504; called by muse, mutect2, varscan2
- DAG1 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs562046526, COSV58184197; called by muse, mutect2, varscan2
- DBF4B | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.787); catalogued as COSV59260320; called by muse, mutect2, varscan2
- DCBLD2 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV58789231; called by muse, mutect2, varscan2
- DDX19A | c.1189G>C p.D397H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56359757; called by muse, mutect2, varscan2
- DDX20 | c.640G>C p.D214H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63831026; called by muse, mutect2, varscan2
- DDX21 | c.1990G>C p.E664Q | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV62555663; called by muse, mutect2, varscan2
- DEFB114 | c.209G>C p.*70Sext*? | Nonstop Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as COSV59037815; called by muse, mutect2, varscan2
- DENND4C | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66822078; called by muse, mutect2, varscan2
- DESI2 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV55641120; called by muse, mutect2, varscan2
- DGKG | c.1018G>T p.V340L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV53964633; called by muse, mutect2, varscan2
- DHRS9 | c.830C>G p.P277R | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59139819; called by muse, mutect2, varscan2
- DHX29 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV52418127; called by muse, mutect2, varscan2
- DHX32 | c.1593G>C p.L531F | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0.185); catalogued as COSV52939866; called by muse, mutect2, varscan2
- DIDO1 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.318); catalogued as COSV56621069; called by muse, mutect2, varscan2
- DIP2A | c.4639G>A p.E1547K | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV59476951; called by muse, mutect2, varscan2
- DIS3L2 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99805989; called by muse, mutect2, varscan2
- DMBT1 | c.6316C>T p.H2106Y (on ENST00000338354 / NM_001377530.1; = p.H1349Y on NM_004406.3) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57542561; called by muse, mutect2, varscan2
- DNAH1 | c.5125C>G p.P1709A | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70228537, COSV70231516; called by muse, mutect2, varscan2
- DNAH17 | c.7249G>C p.E2417Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV67753523; called by muse, mutect2, varscan2
- DNAH2 | c.7033G>A p.E2345K | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs779213701, COSV66718786; called by muse, mutect2, varscan2
- DNAI2 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | catalogued as COSV56758407; called by muse, varscan2
- DNAI2 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV56758416; called by muse, mutect2, varscan2
- DNAJB5 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs778677308, COSV56625402; called by muse, mutect2, varscan2
- DNMT1 | c.2850C>G p.I950M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.091); catalogued as COSV61579061; called by muse, mutect2, varscan2
- DOC2A | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV58751296; called by muse, mutect2, varscan2
- DOCK8 | c.488T>A p.F163Y | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.819); catalogued as COSV66633924; called by muse, mutect2, varscan2
- DOCK9 | c.1967C>G p.S656C (on ENST00000376460 / NM_001366676.2; = p.S657C on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as COSV100240963, COSV59627432; called by muse, mutect2, varscan2
- DOP1A | c.6781G>A p.D2261N | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1465786138, COSV52709709; called by muse, mutect2, varscan2
- DSN1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as COSV65518881; called by muse, mutect2, varscan2
- DSPP | c.2536G>A p.D846N | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as rs776496447, COSV56810028; called by muse, mutect2
- DST | c.22103G>C p.R7368T (on ENST00000361203 / NM_001374722.1; = p.R5078T on NM_015548.5) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.583); catalogued as COSV55011551; called by muse, mutect2, varscan2
- DTNB | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.096); catalogued as COSV56476080; called by muse, mutect2, varscan2
- DUSP16 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.166); catalogued as COSV53807469; called by muse, mutect2, varscan2
- DUSP5 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as rs370573010, COSV63645422, COSV63645794; called by muse, mutect2, varscan2
- EBF2 | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 44/51 reads (86%) | catalogued as COSV68776285; called by muse, mutect2, varscan2
- EDF1 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56375630; called by muse, mutect2, varscan2
- EEF1AKNMT | c.281G>A p.R94Q (on ENST00000361735 / NM_015935.5; = p.R8Q on NM_014955.3) | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.357); catalogued as rs1045158754, COSV62282959; called by muse, mutect2, varscan2
- EFR3A | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as COSV54453760, COSV54456403; called by muse, mutect2, varscan2
- EGFR | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV51796224; called by muse, mutect2, varscan2
- EHD3 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as COSV59030310; called by muse, mutect2, varscan2
- EIF2AK4 | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 35/42 reads (83%) | SIFT tolerated (0.85); PolyPhen benign (0.335); catalogued as COSV99774497; called by muse, mutect2, varscan2
- EIF3A | c.3686G>C p.R1229T | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.057); catalogued as COSV64960497; called by muse, mutect2, varscan2
- EIF3H | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV52666350; called by muse, mutect2, varscan2
- EIF4G3 | c.2884G>C p.E962Q | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as COSV99943974; called by muse, mutect2, varscan2
- ELANE | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.797); catalogued as rs199659114, CM097555, COSV55047990, COSV55049131; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ELF3 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.306); catalogued as COSV62838180; called by muse, mutect2, varscan2
- ELFN2 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs770737478, COSV68744460; called by muse, mutect2, varscan2
- ELOVL2 | c.448C>G p.H150D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100675823, COSV61154991; called by muse, mutect2, varscan2
- ENDOU | c.863C>G p.S288* (on ENST00000422538 / NM_001172439.2; = p.S247* on NM_006025.4) | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV57464937, COSV57465932; called by muse, mutect2, varscan2
- ENPEP | c.203C>G p.S68* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV54450318, COSV54457280; called by muse, mutect2, varscan2
- EPPK1 | c.5596G>A p.D1866N | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as rs369677374; called by muse, mutect2, varscan2
- ESR1 | c.617A>G p.K206R | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52789687, COSV52802498; called by muse, mutect2, varscan2
- ESYT1 | c.1618G>T p.E540* | Nonsense Mutation (SNP) | VAF 16/31 reads (52%) | catalogued as COSV57272694; called by muse, mutect2, varscan2
- ETV6 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV67149690; called by muse, mutect2, varscan2
- EVC2 | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); catalogued as COSV60392839; called by muse, mutect2, varscan2
- EVC2 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV60388948; called by muse, mutect2, varscan2
- EVPL | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0.039); catalogued as COSV56910415; called by muse, mutect2, varscan2
- EXOC3L1 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 9/11 reads (82%) | catalogued as COSV52046136; called by muse, mutect2, varscan2
- EXOC8 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 32/73 reads (44%) | catalogued as COSV50478074; called by muse, mutect2, varscan2
- EXOC8 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as rs139487910, COSV50478076; called by muse, mutect2, varscan2
- EZH2 | c.2069C>T p.S690L (on ENST00000460911 / NM_001203247.2; = p.S695L on NM_004456.5) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as CM1110543, COSV57449243; called by muse, mutect2
- F8A1 | c.958C>G p.L320V | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV57705056; called by mutect2, varscan2
- FAAP100 | c.2278G>A p.D760N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as COSV59885170; called by muse, mutect2, varscan2
- FAM133A | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.003); catalogued as COSV59075116; called by muse, mutect2, varscan2
- FAM133B | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV70075593; called by muse, mutect2, varscan2
- FAM193A | c.90C>G p.F30L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.776); catalogued as COSV61193522; called by muse, mutect2
- FAM47B | c.1291G>A p.G431R | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.58); PolyPhen benign (0.036); catalogued as rs754058778, COSV61453576; called by muse, mutect2, varscan2
- FAM47C | c.1543T>C p.S515P | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1209694163, COSV63725078; called by muse, varscan2
- FAM83D | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV54157302; called by muse, mutect2, varscan2
- FAM83G | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as COSV58756629, COSV58759158; called by muse, mutect2, varscan2
- FANCI | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV55526464; called by muse, mutect2
- FAT2 | c.1307C>G p.S436* | Nonsense Mutation (SNP) | VAF 24/48 reads (50%) | catalogued as COSV55818798, COSV55823429; called by muse, mutect2, varscan2
- FBN2 | c.2453G>C p.R818T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV52510067; called by muse, mutect2, varscan2
- FBXL16 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV50197346; called by muse, mutect2, varscan2
- FER1L5 | c.4213G>C p.E1405Q (on ENST00000623019; = p.E1378Q on NM_001293083.2) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV101208847; called by muse, mutect2, varscan2
- FER1L5 | c.4252C>G p.L1418V (on ENST00000623019; = p.L1391V on NM_001293083.2) | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV101208848; called by muse, mutect2, varscan2
- FERMT2 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.291); catalogued as COSV58406591; called by muse, mutect2, varscan2
- FGF16 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 64/99 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV101466313; called by muse, mutect2, varscan2
- FKRP | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV59358669; called by muse, mutect2
- FOCAD | c.1937C>G p.S646C | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58098073; called by muse, mutect2, varscan2
- FOXO1 | c.1595C>T p.S532F | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0.054); catalogued as COSV65426588, COSV65428095; called by muse, mutect2, varscan2
- FOXP2 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63483439, COSV63486063; called by muse, mutect2, varscan2
- FREM1 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV101084242; called by muse, mutect2, varscan2
- FRY | c.1519G>C p.D507H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV66569478, COSV66576198; called by muse, mutect2, varscan2
- FRY | c.7570G>A p.E2524K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs768008979, COSV66569507; called by muse, mutect2, varscan2
- FSTL5 | c.997C>G p.H333D | Missense Mutation (SNP) | VAF 50/84 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60193422; called by muse, mutect2, varscan2
- G6PC | c.846G>C p.E282D | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV53830902; called by muse, mutect2, varscan2
- GABARAP | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as COSV56641884; called by muse, mutect2, varscan2
- GABRG3 | c.370G>C p.G124R | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV61516961; called by muse, mutect2, varscan2
- GAK | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58504349; called by muse, mutect2, varscan2
- GALR2 | c.830C>G p.S277W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV57162495; called by muse, varscan2
- GCAT | c.645G>T p.Q215H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV50648948; called by muse, varscan2
- GCAT | c.727G>C p.G243R | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV50648961; called by muse, varscan2
- GEN1 | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV58056400; called by muse, mutect2, varscan2
- GJD2 | c.536C>A p.S179* | Nonsense Mutation (SNP) | VAF 62/92 reads (67%) | catalogued as COSV99290686; called by muse, mutect2, varscan2
- GLIS3 | c.2227G>A p.G743R | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs771158269, COSV60928273; called by muse, mutect2, varscan2
- GLMP | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1219162164, COSV55294965; called by muse, mutect2, varscan2
- GNB3 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV99301145; called by muse, mutect2, varscan2
- GPATCH8 | c.3579C>G p.F1193L | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV59194659; called by muse, mutect2, varscan2
- GPHB5 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs191071731; called by muse, mutect2, varscan2
- GPR18 | c.293G>C p.G98A | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as COSV61621163; called by muse, mutect2, varscan2
- GPRASP1 | c.3463G>C p.E1155Q | Missense Mutation (SNP) | VAF 53/86 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100850955; called by muse, mutect2, varscan2
- GPRIN1 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56138188; called by muse, mutect2, varscan2
- GRHL3 | c.991G>C p.E331Q (on ENST00000350501 / NM_198174.3; = p.E336Q on NM_021180.3) | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52566178; called by muse, mutect2, varscan2
- GRIA1 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV53600946; called by muse, mutect2, varscan2
- GRIPAP1 | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV54413890; called by muse, mutect2, varscan2
- GRM6 | c.2539C>G p.P847A | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51449553, COSV99179559; called by muse, varscan2
- GRM7 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV63141931; called by muse, mutect2, varscan2
- GTF2H3 | c.926G>C p.*309Sext*2 | Nonstop Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV57458738; called by muse, mutect2, varscan2
- GTF3C2 | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV53126337; called by muse, mutect2, varscan2
- GZMK | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs759647342, COSV50244994; called by muse, mutect2, varscan2
- H1-10 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.174); catalogued as COSV61549592, COSV61549829; called by muse, mutect2, varscan2
- H1-2 | c.387G>C p.K129N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as rs766767455, COSV59190607; called by muse, mutect2, varscan2
- H2BC4 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as rs879122516, COSV58414927, COSV58416609, COSV58417570; called by muse, mutect2, varscan2
- HARS1 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.009); catalogued as COSV100047624; called by muse, mutect2, varscan2
- HCN1 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV57507706; called by muse, mutect2, varscan2
- HDX | c.1808C>G p.S603C | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV52972771, COSV52976185; called by muse, mutect2, varscan2
- HEATR1 | c.1693delinsAA p.E565Kfs*13 | Frame Shift Ins (INS) | VAF 18/53 reads (34%) | catalogued as COSV63980953; called by pindel, varscan2*
- HECTD1 | c.6047C>T p.S2016L | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV101237326, COSV101237352; called by muse, mutect2, varscan2
- HEG1 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.593); catalogued as COSV60761579; called by muse, mutect2
- HELZ2 | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT tolerated (0.69); PolyPhen benign (0.036); catalogued as rs143335677; called by muse, mutect2, varscan2
- HEXD | c.1381C>G p.L461V (on ENST00000327949 / NM_001369487.1; = p.L490= on NM_173620.3) | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.043); catalogued as COSV60063824; called by muse, mutect2, varscan2
- HIF1A | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.144); catalogued as rs755825658, COSV60189123; called by muse, mutect2, varscan2
- HIPK1 | c.787C>G p.H263D | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65784404; called by muse, mutect2, varscan2
- HIVEP2 | c.5185C>G p.Q1729E | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.755); catalogued as COSV50010358; called by muse, mutect2, varscan2
- HIVEP2 | c.4786G>T p.E1596* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV50005281, COSV50010400; called by muse, mutect2, varscan2
- HORMAD1 | c.1154G>C p.R385T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV55045996; called by muse, mutect2, varscan2
- HOXB2 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as COSV57486673; called by muse, mutect2, varscan2
- HP1BP3 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV56562337; called by muse, mutect2, varscan2
- HSH2D | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770936437, COSV53737889; called by muse, mutect2, varscan2
- HSH2D | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV53737900; called by muse, mutect2, varscan2
- HSP90AA1 | c.1922C>G p.S641C | Missense Mutation (SNP) | VAF 63/73 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53488450; called by muse, mutect2, varscan2
- HSPBAP1 | c.1138G>T p.D380Y | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV60242156; called by muse, mutect2, varscan2
- HSPH1 | c.1661C>G p.S554C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV60711251; called by muse, mutect2, varscan2
- HTR3B | c.810G>C p.R270S | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs549253438, COSV52744289; called by muse, mutect2, varscan2
- IFI44L | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV60727451; called by muse, mutect2
- IFIT1B | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV65663395; called by muse, mutect2, varscan2
- IGBP1 | c.729C>G p.F243L | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV60556131; called by muse, mutect2, varscan2
- IGSF9 | c.3200G>A p.R1067Q (on ENST00000368094 / NM_001135050.2; = p.R1051Q on NM_020789.4) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.551); catalogued as rs770700069, COSV57421539; called by muse, mutect2, varscan2
- IL4R | c.1680G>C p.Q560H | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50142144; called by muse, mutect2, varscan2
- IMPA2 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV52318591; called by muse, mutect2, varscan2
- IMPG2 | c.2416G>C p.D806H | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV99515302; called by muse, mutect2, varscan2
- INPP4A | c.975G>C p.L325F | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV50790631; called by muse, mutect2, varscan2
- INTS1 | c.3586G>A p.E1196K | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs368845872; called by muse, mutect2, varscan2
- INTS3 | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as COSV59677257; called by muse, mutect2, varscan2
- INTS5 | c.2353C>T p.H785Y | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs761220419, COSV100399564; called by muse, mutect2, varscan2
- INTS6 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.87); PolyPhen benign (0.013); catalogued as COSV60877881; called by muse, mutect2, varscan2
- IPO4 | c.2936C>T p.P979L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs778843210, COSV61016486; called by muse, mutect2, varscan2
- IPO7 | c.321-1G>C p.X107_splice | Splice Site (SNP) | VAF 27/80 reads (34%) | catalogued as COSV65684894; called by muse, mutect2, varscan2
- IPO7 | c.3044G>T p.G1015V | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV101121784, COSV65684901; called by muse, mutect2, varscan2
- IRF7 | c.676G>C p.E226Q (on ENST00000397566; = p.E213Q on NM_001572.5) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs375250292; called by muse, mutect2, varscan2
- ITGA8 | c.2373-1G>A p.X791_splice | Splice Site (SNP) | VAF 46/94 reads (49%) | catalogued as COSV65228161; called by muse, mutect2, varscan2
- ITPRID2 | c.3401C>T p.S1134L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV57471407; called by muse, mutect2, varscan2
- ITSN1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV101180480; called by muse, mutect2, varscan2
- JADE2 | c.83C>G p.S28* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as COSV50915473, COSV99253613; called by muse, mutect2, varscan2
- JAML | c.492C>A p.H164Q (on ENST00000356289 / NM_001098526.2; = p.H154Q on NM_153206.3) | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT tolerated (0.44); PolyPhen benign (0.059); catalogued as COSV99409435; called by muse, mutect2, varscan2
- JMJD6 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV57971816; called by muse, mutect2, varscan2
- KALRN | c.5871G>C p.K1957N (on ENST00000360013 / NM_001024660.4; = p.K260N on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.709); catalogued as COSV52255392; called by muse, mutect2, varscan2
- KAT5 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.177); catalogued as COSV57729291; called by muse, mutect2, varscan2
- KAT5 | c.924G>C p.K308N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57729508; called by muse, mutect2, varscan2
- KATNAL1 | c.446C>G p.S149C | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as COSV66063194; called by muse, mutect2, varscan2
- KBTBD7 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.047); catalogued as COSV65266355; called by muse, mutect2, varscan2
- KCNJ14 | c.279C>G p.F93L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53518525; called by muse, mutect2, varscan2
- KDR | c.4063C>G p.P1355A | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs747831962, COSV55764187; called by muse, mutect2, varscan2
- KIAA1522 | c.2518C>G p.P840A (on ENST00000373480 / NM_001198972.2; = p.P899A on NM_020888.3) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV53864192, COSV99615129; called by muse, mutect2, varscan2
- KIAA1522 | c.2666C>G p.S889* (on ENST00000373480 / NM_001198972.2; = p.S948* on NM_020888.3) | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV53864216; called by muse, mutect2, varscan2
- KIF11 | c.1357G>C p.D453H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV53270376; called by muse, mutect2, varscan2
- KIF13A | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52449520; called by muse, mutect2, varscan2
- KIF21A | c.2338G>A p.E780K (on ENST00000361418 / NM_001378440.1; = p.E767K on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs778531745, COSV62770845; called by muse, mutect2, varscan2
- KIF24 | c.2757G>C p.W919C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV52658689; called by muse, mutect2, varscan2
- KIF6 | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV54675794; called by muse, mutect2, varscan2
- KIT | c.2709G>A p.M903I | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV55398687, COSV99855027; called by muse, mutect2, varscan2
- KLC1 | c.77C>G p.S26C | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV55807631; called by muse, mutect2, varscan2
- KLHL20 | c.1349G>T p.R450I | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52941709; called by muse, mutect2, varscan2
- KLHL3 | c.656C>G p.S219* | Nonsense Mutation (SNP) | VAF 29/60 reads (48%) | catalogued as COSV59054005; called by muse, mutect2, varscan2
- KLHL31 | c.325C>G p.Q109E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.089); catalogued as COSV63881780; called by muse, mutect2, varscan2
- KLRD1 | c.247A>G p.N83D | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.078); catalogued as COSV60273615; called by muse, mutect2, varscan2
- KMT2A | c.4822G>A p.E1608K | Missense Mutation (SNP) | VAF 44/50 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63283617, COSV63285357; called by muse, mutect2, varscan2
- KMT2B | c.3959G>C p.G1320A | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.525); catalogued as COSV55860471; called by muse, mutect2, varscan2
- KMT2C | c.2930G>T p.C977F | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100070596, COSV51457712; called by muse, mutect2
- KNDC1 | c.1856C>G p.S619* | Nonsense Mutation (SNP) | VAF 37/76 reads (49%) | catalogued as COSV58836180; called by muse, mutect2, varscan2
- KNTC1 | c.3889G>A p.E1297K | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV61079925; called by muse, mutect2, varscan2
- KPNA3 | c.1525G>C p.D509H | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as COSV55504513; called by muse, mutect2, varscan2
- KRT33A | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV50365634; called by muse, mutect2, varscan2
- KRT7 | c.134C>G p.S45* | Nonsense Mutation (SNP) | VAF 4/8 reads (50%) | catalogued as COSV59330763; called by mutect2, varscan2
- KRT85 | c.441G>C p.Q147H | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV57736717, COSV57736745; called by muse, mutect2, varscan2
- KRTAP10-11 | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58177730; called by muse, mutect2, varscan2
- KRTAP5-2 | c.23G>C p.R8T | Missense Mutation (SNP) | VAF 101/180 reads (56%) | PolyPhen benign (0); catalogued as COSV69014881; called by muse, mutect2, varscan2
- L1CAM | c.1564C>T p.Q522* | Nonsense Mutation (SNP) | VAF 91/147 reads (62%) | catalogued as COSV62827986; called by muse, mutect2, varscan2
- LARGE1 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV61661260; called by muse, mutect2, varscan2
- LARP1 | c.2797G>C p.E933Q (on ENST00000518297 / NM_033551.3; = p.E856Q on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV60426627; called by muse, mutect2, varscan2
- LBR | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55288713; called by muse, mutect2, varscan2
- LCE3C | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.418); catalogued as COSV61610203, COSV61610290; called by muse, mutect2, varscan2
- LCOR | c.2486G>C p.R829T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.786); catalogued as COSV53715622; called by muse, mutect2, varscan2
- LETM1 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57100297; called by muse, mutect2, varscan2
- LGALS9 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV56348734; called by muse, mutect2, varscan2
- LRIF1 | c.1168C>G p.P390A | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.647); catalogued as COSV63897242; called by muse, mutect2, varscan2
- LRP2 | c.13469G>C p.G4490A | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.448); catalogued as COSV55551430; called by muse, mutect2, varscan2
- LRP2 | c.12209C>G p.S4070* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV55551438; called by muse, mutect2, varscan2
- LRP5 | c.1802G>A p.G601E | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53715013; called by muse, mutect2, varscan2
- LRRC58 | c.438G>C p.Q146H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1294483258, COSV55230077; called by muse, mutect2, varscan2
- LSS | c.999C>G p.I333M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.942); catalogued as COSV62700737; called by muse, mutect2, varscan2
- LURAP1L | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV59984538; called by muse, mutect2, varscan2
- LY6G5B | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 31/77 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.23); catalogued as COSV65507860; called by muse, mutect2, varscan2
- LYPD6 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.167); catalogued as COSV61939979; called by muse, mutect2, varscan2
- MACF1 | c.15031G>T p.E5011* (on ENST00000372915; = p.E2944* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV57119217; called by muse, mutect2, varscan2
- MADD | c.4798G>A p.E1600K | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); catalogued as COSV57026644; called by muse, mutect2, varscan2
- MAEA | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.688); catalogued as COSV53262277; called by muse, mutect2, varscan2
- MAGEL2 | c.2145G>A p.M715I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as rs369371337; called by muse, mutect2, varscan2
- MANF | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as COSV56518785; called by muse, mutect2, varscan2
- MAP1B | c.2476G>C p.E826Q | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.946); catalogued as rs1394835203, COSV57098233; called by muse, mutect2, varscan2
- MAP3K1 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.194); catalogued as COSV68123216; called by muse, mutect2, varscan2
- MAP3K19 | c.2414C>G p.S805* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100209064, COSV100209511, COSV59638494; called by muse, mutect2, varscan2
- MAP3K5 | c.2299C>T p.R767C | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs757418759, COSV62888967; called by muse, mutect2, varscan2
- MAPKAPK3 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV63597307; called by muse, mutect2, varscan2
- MARF1 | c.2466G>C p.K822N | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); catalogued as COSV60022921; called by muse, mutect2, varscan2
- MARS2 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV99986557; called by muse, mutect2, varscan2
- MAST1 | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.27); catalogued as rs138461183; called by muse, mutect2, varscan2
- MAST3 | c.2558C>G p.S853C | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.962); catalogued as COSV53220180; called by muse, mutect2, varscan2
- MAST4 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.026); catalogued as COSV68236624; called by muse, mutect2, varscan2
- MBD3L2 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1162927718, COSV100421446; called by muse, mutect2
- MBD5 | c.635C>G p.S212C | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68696827; called by muse, mutect2, varscan2
- MBOAT7 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs759231014, COSV55475572; called by muse, mutect2, varscan2
- MC2R | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.995); catalogued as COSV59617916; called by muse, mutect2, varscan2
- MCC | c.2329G>C p.E777Q | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56728153; called by muse, mutect2, varscan2
- MDN1 | c.13360G>C p.D4454H | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV65521025; called by muse, mutect2, varscan2
- MDN1 | c.13228G>C p.E4410Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV65521030; called by muse, mutect2, varscan2
- MDN1 | c.5800G>C p.E1934Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as COSV101021173; called by muse, mutect2, varscan2
- MED11 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.102); catalogued as rs766639693, COSV53411583; called by muse, mutect2, varscan2
- MED24 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV62418443; called by muse, mutect2, varscan2
- MEF2D | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61728060; called by muse, mutect2, varscan2
- MEPE | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as COSV63072622; called by muse, mutect2, varscan2
- MFAP4 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs372745312; called by muse, mutect2, varscan2
- MFSD11 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs765041697, COSV60623352; called by muse, mutect2, varscan2
- MGAT5 | c.2086G>A p.D696N | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.088); catalogued as COSV56096129; called by muse, mutect2, varscan2
- MKLN1 | c.1984G>T p.D662Y | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV61760782; called by muse, varscan2
- MLLT11 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64462313; called by muse, mutect2, varscan2
- MMAA | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs771044996, COSV55579975; called by muse, mutect2, varscan2
- MMP2 | c.1116G>C p.K372N | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54598741; called by muse, mutect2, varscan2
- MN1 | c.3924C>G p.I1308M | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as COSV56558044; called by muse, mutect2, varscan2
- MORC3 | c.1155G>C p.M385I | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.039); catalogued as COSV68203586; called by muse, mutect2, varscan2
- MPDZ | c.3985G>A p.E1329K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.284); catalogued as COSV59917469; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2062G>C p.E688Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1019914790, COSV64055400; called by muse, mutect2, varscan2
- MRGPRF | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.426); catalogued as rs1481354874, COSV57995813; called by muse, mutect2, varscan2
- MSH4 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.137); catalogued as COSV54202052; called by muse, mutect2, varscan2
- MTMR11 | c.1160C>T p.S387L (on ENST00000439741 / NM_001145862.2; = p.S315L on NM_181873.3) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1364738464, COSV54965275; called by muse, mutect2, varscan2
- MTTP | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV55505583; called by muse, mutect2, varscan2
- MUC16 | c.22417C>T p.P7473S | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.818); catalogued as COSV67457303; called by muse, mutect2, varscan2
- MUC16 | c.16007C>T p.S5336F | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.612); catalogued as COSV67462759; called by muse, mutect2, varscan2
- MUC16 | c.9853C>G p.L3285V | Missense Mutation (SNP) | VAF 75/174 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV67455399, COSV67462764; called by muse, mutect2, varscan2
- MUC17 | c.2126C>G p.S709* | Nonsense Mutation (SNP) | VAF 38/98 reads (39%) | catalogued as COSV60287347; called by muse, mutect2, varscan2
- MUC5B | c.10223C>G p.S3408* | Nonsense Mutation (SNP) | VAF 38/149 reads (26%) | catalogued as COSV71591769; called by muse, mutect2, varscan2
- MUC5B | c.15242C>T p.S5081F | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.881); catalogued as COSV71591771; called by muse, varscan2
- MYBBP1A | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54597233; called by muse, mutect2, varscan2
- MYCBPAP | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as rs376168122, COSV60407405; called by muse, mutect2, varscan2
- MYH13 | c.666C>G p.I222M | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52827167; called by muse, mutect2, varscan2
- MYH2 | c.4294G>A p.E1432K | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.746); catalogued as rs747081221, COSV55435723, COSV55437149; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH6 | c.2481G>C p.K827N | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62449989, COSV62454840; called by muse, mutect2, varscan2
- MYL12A | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV54182262; called by muse, mutect2, varscan2
- MYO7A | c.1106G>A p.C369Y | Missense Mutation (SNP) | VAF 76/86 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV68684543, COSV68686643; called by muse, mutect2, varscan2
- MYOF | c.2888C>T p.S963L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as COSV63703537; called by muse, mutect2, varscan2
- MYOM3 | c.4165G>A p.E1389K | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.266); catalogued as COSV58393298; called by muse, mutect2, varscan2
- MZB1 | c.557G>C p.R186T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as COSV56172048; called by muse, varscan2
- MZB1 | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.111); catalogued as COSV56172066; called by muse, varscan2
- N4BP2L2 | c.862C>G p.H288D | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as COSV57228244; called by muse, mutect2, varscan2
- N6AMT1 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as rs761729543, COSV58134310, COSV58134349; called by muse, mutect2, varscan2
- NAA35 | c.1951C>G p.Q651E | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64484717; called by muse, mutect2, varscan2
- NAF1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV56804246; called by muse, mutect2, varscan2
- NAV1 | c.5149G>A p.D1717N | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as COSV55217127; called by muse, mutect2, varscan2
- NAV2 | c.4904C>T p.S1635L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1185910379, COSV60658915; called by muse, mutect2, varscan2
- NCAM2 | c.2401G>C p.E801Q | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV53072285, COSV53098666, COSV99525968; called by muse, mutect2, varscan2
- NCAPH | c.1051G>C p.D351H | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53634777, COSV53636227; called by muse, mutect2, varscan2
- NCOA1 | c.1715G>C p.R572T | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.728); catalogued as COSV56043198; called by muse, mutect2, varscan2
- NCOA7 | c.2767G>A p.D923N | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV57654946; called by muse, mutect2, varscan2
- NDRG3 | c.813C>T p.V271= (on ENST00000349004 / NM_032013.4; = p.V259= on NM_022477.4) | Splice Region (SNP) | VAF 5/17 reads (29%) | catalogued as rs777659603, COSV62421148; called by muse, mutect2
- NDST4 | c.1208A>G p.K403R | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV52118065; called by muse, mutect2, varscan2
- NEK1 | c.2221C>G p.H741D | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs764750478, COSV101455929, COSV71455887; called by muse, mutect2, varscan2
- NELFCD | c.688G>C p.E230Q (on ENST00000602795; = p.E212Q on NM_198976.4) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.478); catalogued as COSV59746052; called by muse, mutect2, varscan2
- NEURL4 | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100224099; called by mutect2, varscan2
- NFATC1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV53699648; called by muse, mutect2, varscan2
- NHS | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1309437457, COSV66274407; called by muse, mutect2, varscan2
- NLRP5 | c.1678G>T p.E560* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as COSV66764104, COSV66764204; called by muse, mutect2, varscan2
- NOA1 | c.1919G>C p.R640T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV51736779, COSV51738668; called by muse, mutect2, varscan2
- NOCT | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54935920; called by muse, mutect2, varscan2
- NOXO1 | c.745G>A p.E249K (on ENST00000397280 / NM_172168.3; = p.E243K on NM_144603.4) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as rs1264960922, COSV50191463; called by muse, mutect2, varscan2
- NPAP1 | c.2138C>T p.S713F | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV61506472; called by muse, mutect2, varscan2
- NPY1R | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.993); catalogued as rs867894537, COSV56714314; called by muse, mutect2, varscan2
- NRG3 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs560019942, COSV64554148; called by muse, mutect2, varscan2
- NRXN2 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.325); catalogued as COSV55452297; called by muse, mutect2, varscan2
- NUDT10 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as rs1394121098, COSV100726805, COSV62853949; called by muse, mutect2, varscan2
- NUP62 | c.199C>G p.P67A | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV61311963; called by muse, varscan2
- NUP85 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1350790812, COSV55463908; called by muse, mutect2, varscan2
- OAS1 | c.1004G>C p.W335S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.038); catalogued as COSV52535559; called by muse, mutect2, varscan2
- OBSCN | c.1825C>A p.L609M | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV52770039; called by muse, mutect2, varscan2
- OBSCN | c.21362C>T p.S7121F | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1300334414, COSV62326680; called by muse, mutect2, varscan2
- OR10G2 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs777385052, COSV73390345, COSV73390359; called by muse, mutect2
- OR1I1 | c.995G>C p.R332T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.05); catalogued as COSV52917867; called by muse, mutect2, varscan2
- OR1S1 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV58706958; called by muse, mutect2, varscan2
- OR1S1 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as COSV58706964; called by muse, mutect2, varscan2
- OR2T33 | c.102G>C p.L34F | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV58815197, COSV58815531; called by muse, varscan2
- OR4K13 | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV59859540; called by muse, mutect2, varscan2
- OR4K17 | c.671C>G p.T224S | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as COSV100210616; called by muse, mutect2
- OR5M1 | c.420C>G p.I140M | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV73202023, COSV73202103; called by muse, mutect2, varscan2
- OR8G5 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 112/133 reads (84%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.118); catalogued as COSV100422164; called by muse, mutect2, varscan2
- OR8H3 | c.847C>G p.P283A | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV57908711; called by muse, mutect2, varscan2
- ORC2 | c.1293C>A p.L431= | Splice Region (SNP) | VAF 16/42 reads (38%) | catalogued as COSV99309508; called by muse, varscan2
- OSBPL9 | c.295C>G p.L99V | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.396); catalogued as COSV61868144, COSV61869338; called by muse, varscan2
- OSGEPL1 | c.930G>C p.Q310H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.188); catalogued as COSV51462409; called by muse, mutect2, varscan2
- OTOF | c.2094G>T p.R698S | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); catalogued as COSV55501982, COSV55509719; called by muse, mutect2, varscan2
- OTOGL | c.1288C>T p.L430F (on ENST00000547103; = p.L421F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV72006527; called by muse, mutect2, varscan2
- OTOP1 | c.1697G>C p.R566P | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs554408396, COSV56390561, COSV56392886, COSV99587400; called by muse, mutect2, varscan2
- OXSR1 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV61258545; called by muse, mutect2, varscan2
- PAGE2B | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV100894278, COSV66611320; called by muse, mutect2, varscan2
- PAICS | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | PolyPhen benign (0.25); catalogued as COSV51708578; called by muse, mutect2, varscan2
- PANK3 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53322899; called by muse, mutect2, varscan2
- PAPSS2 | c.12C>G p.I4M | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV63263282; called by muse, mutect2, varscan2
- PAPSS2 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100753600, COSV63263289; called by muse, mutect2, varscan2
- PARD3 | c.1892C>G p.S631C | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0.419); catalogued as rs779872179, COSV60749156; called by muse, mutect2, varscan2
- PARVB | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV58686438, COSV58688666; called by muse, mutect2, varscan2
- PCARE | c.3763G>C p.E1255Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs748527009, COSV59054640; called by muse, mutect2, varscan2
- PCCB | c.541C>T p.L181= | Splice Region (SNP) | VAF 14/58 reads (24%) | catalogued as rs991870747, COSV52444922; called by muse, mutect2, varscan2
- PCDH19 | c.2728G>A p.E910K (on ENST00000373034 / NM_001184880.2; = p.E862K on NM_020766.3) | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV55262022; called by muse, mutect2, varscan2
- PCDHA5 | c.446C>G p.S149W | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65351925; called by muse, mutect2, varscan2
- PCDHB15 | c.554G>C p.R185P | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV50889694, COSV50909484; called by muse, mutect2, varscan2
- PCDHB3 | c.2298C>G p.F766L | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.065); catalogued as COSV50571056; called by muse, mutect2, varscan2
- PCGF1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.165); catalogued as COSV52043017; called by muse, mutect2, varscan2
- PCLO | c.12881G>C p.R4294T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61632311; called by muse, mutect2
- PCMTD2 | c.191C>G p.S64* | Nonsense Mutation (SNP) | VAF 74/108 reads (69%) | catalogued as COSV55060258, COSV55060704; called by muse, mutect2, varscan2
- PCNX2 | c.1444C>A p.H482N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV50797672; called by muse, mutect2, varscan2
- PCNX2 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as COSV50797721; called by muse, mutect2, varscan2
- PCOLCE2 | c.378G>C p.M126I | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV55998856; called by muse, mutect2, varscan2
- PCYT2 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV58711201; called by muse, mutect2, varscan2
- PDAP1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.292); catalogued as COSV63299142; called by muse, mutect2, varscan2
- PDHB | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV104406482, COSV57056820; called by muse, mutect2, varscan2
- PDZD2 | c.5155C>A p.H1719N | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV56857168, COSV56869741; called by muse, mutect2, varscan2
- PER1 | c.3426G>A p.M1142I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57919242; called by muse, mutect2, varscan2
- PHB2 | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54641256, COSV54641871; called by muse, mutect2, varscan2
- PHOSPHO2 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV55866960, COSV55867990, COSV99067975; called by muse, mutect2, varscan2
- PHOSPHO2 | c.346G>C p.D116H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV55866967; called by mutect2, varscan2
- PIAS3 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV57907207; called by muse, mutect2, varscan2
- PIK3R3 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV53106904; called by muse, mutect2, varscan2
- PIM1 | c.152C>G p.S51W | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs551680157, COSV65165390, COSV65165828; called by muse, mutect2, varscan2
- PIRT | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV74119885; called by muse, mutect2, varscan2
- PITPNA | c.183C>G p.I61M | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57933926; called by muse, mutect2, varscan2
- PKD1 | c.12844G>C p.D4282H (on ENST00000262304 / NM_001009944.3; = p.D4281H on NM_000296.4) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.628); catalogued as COSV51915451; called by muse, mutect2, varscan2
- PKHD1 | c.2988G>C p.L996F | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV100582600, COSV100583141; called by muse, mutect2, varscan2
- PKHD1L1 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs762724318, COSV65742157; called by muse, mutect2, varscan2
- PKMYT1 | c.428C>A p.S143* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as COSV51891398; called by muse, mutect2, varscan2
- PLCB1 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62048776; called by muse, mutect2, varscan2
- PLCXD3 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV60608310; called by muse, mutect2, varscan2
- PLEKHM3 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs375834227; called by muse, mutect2, varscan2
- PMVK | c.158A>T p.Q53L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV63785801; called by muse, mutect2, varscan2
- PNISR | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV65079346; called by muse, mutect2, varscan2
- POLK | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54034763; called by muse, varscan2
- POLK | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.424); catalogued as COSV54034795; called by muse, varscan2
- POLQ | c.4816C>T p.Q1606* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV51750784; called by muse, mutect2, varscan2
- POLR1B | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV54497553, COSV54505265; called by muse, mutect2, varscan2
- POLR3C | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV61936421; called by muse, mutect2, varscan2
- POT1 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV62929676; called by muse, mutect2, varscan2
- PPP1R3F | c.1751C>G p.S584C | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as COSV50018213; called by muse, mutect2, varscan2
- PPP1R9A | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV56891121, COSV56895367, COSV56896971; called by muse, mutect2, varscan2
- PPP4R4 | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV58554211; called by muse, mutect2, varscan2
- PPRC1 | c.3378G>C p.Q1126H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs947955237, COSV53385022; called by muse, mutect2, varscan2
- PPT2 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52998128; called by muse, mutect2, varscan2
- PRAMEF2 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 89/184 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs776428150, COSV53574151; called by muse, mutect2, varscan2
- PRCC | c.1396G>T p.E466* | Nonsense Mutation (SNP) | VAF 23/44 reads (52%) | catalogued as COSV99618612; called by muse, varscan2
- PRELID2 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.113); catalogued as COSV100597281, COSV58279687; called by muse, mutect2, varscan2
- PRLH | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.74); PolyPhen benign (0.019); catalogued as COSV51255441; called by muse, mutect2, varscan2
- PRMT5 | c.1433C>T p.S478F | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV53545931; called by muse, mutect2, varscan2
- PRODH2 | c.236G>A p.R79Q (on ENST00000301175; = p.R3Q on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs370209287; called by muse, mutect2
- PROM1 | c.681C>G p.F227L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.023); catalogued as COSV71699391; called by muse, mutect2, varscan2
- PROM2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV58297862; called by muse, mutect2, varscan2
- PRSS54 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 69/78 reads (88%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs149972398; called by muse, mutect2, varscan2
- PRTFDC1 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV60774341; called by muse, mutect2, varscan2
- PSG1 | c.711G>A p.P237= | Splice Region (SNP) | VAF 84/184 reads (46%) | catalogued as rs4030951, COSV54946847, COSV54957573; called by muse, mutect2, varscan2
- PSME4 | c.3341C>G p.S1114C | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV66363346, COSV66364687; called by muse, mutect2, varscan2
- PSPC1 | c.1360C>G p.P454A | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV58887947; called by muse, mutect2, varscan2
- PTBP3 | c.1546C>G p.L516V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV57582525; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.722C>T p.S241L (on ENST00000421990 / NM_001136042.2; = p.S223L on NM_025267.3) | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV64182670; called by muse, mutect2, varscan2
- PTK2 | c.34C>T p.H12Y | Missense Mutation (SNP) | VAF 86/130 reads (66%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.977); catalogued as COSV100570021, COSV61792374; called by muse, mutect2, varscan2
- PTPN13 | c.6286G>C p.E2096Q (on ENST00000411767 / NM_080683.3; = p.E2077Q on NM_006264.3) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.939); catalogued as COSV57406601; called by muse, mutect2, varscan2
- PTPRC | c.2104G>C p.D702H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV61410779; called by muse, mutect2, varscan2
- PTPRK | c.2707G>C p.D903H (on ENST00000368215 / NM_001291984.2; = p.D904H on NM_002844.4) | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV63896512; called by muse, mutect2, varscan2
- PTPRS | c.3766-1G>A p.X1256_splice | Splice Site (SNP) | VAF 21/41 reads (51%) | catalogued as rs1453369741, COSV53618403, COSV53640807; called by muse, mutect2, varscan2
- QSER1 | c.4046G>A p.G1349E (on ENST00000399302; = p.G1478E on NM_001076786.3) | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV67900397; called by muse, mutect2, varscan2
- RAC2 | c.486G>C p.Q162H | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV50774231; called by muse, mutect2, varscan2
- RAD23A | c.428C>G p.S143C | Missense Mutation (SNP) | VAF 51/74 reads (69%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.45); catalogued as COSV57124064; called by muse, mutect2, varscan2
- RAD51 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 56/74 reads (76%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV51111510; called by muse, mutect2, varscan2
- RAD51C | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV53612967; called by muse, mutect2, varscan2
- RAD54L2 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56578347, COSV56578895; called by muse, mutect2, varscan2
- RAG2 | c.1044G>C p.L348F | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57557237; called by muse, mutect2, varscan2
- RBBP7 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV58112861; called by muse, mutect2, varscan2
- RBSN | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs1173969945, COSV53792848; called by muse, mutect2, varscan2
- RC3H2 | c.1259G>C p.R420P | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV59011832; called by muse, mutect2, varscan2
- RCAN3 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV100980334; called by muse, varscan2
- RGL4 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.955); catalogued as COSV51943768; called by muse, mutect2, varscan2
- RHCG | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV51515753; called by muse, mutect2, varscan2
- RICTOR | c.1446G>A p.M482I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV57121325; called by muse, mutect2, varscan2
- RIOK2 | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51615446, COSV99299923; called by muse, mutect2, varscan2
- RNF133 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100411416, COSV57361361; called by muse, mutect2, varscan2
- RNF133 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV57361367; called by muse, mutect2, varscan2
- RNF168 | c.1531G>C p.E511Q | Missense Mutation (SNP) | VAF 95/178 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV58837040, COSV58838985; called by muse, mutect2, varscan2
- RNF180 | c.1-1G>C p.X1_splice | Splice Site (SNP) | VAF 16/32 reads (50%) | catalogued as COSV56961622; called by muse, mutect2, varscan2
- RNF213 | c.6744G>C p.K2248N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60394236, COSV60396078; called by muse, mutect2, varscan2
- RNF213 | c.7028G>C p.R2343T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs762352884, COSV60396089; called by muse, mutect2
- RNF213 | c.7888G>A p.E2630K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0.029); catalogued as COSV60396101; called by muse, mutect2, varscan2
- RNMT | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV51084863; called by muse, mutect2, varscan2
- ROBO2 | c.3629C>G p.S1210C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs755603547, COSV59909214; called by muse, mutect2, varscan2
- ROR2 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs746065715, COSV65218647; called by muse, mutect2, varscan2
- ROS1 | c.6694G>T p.E2232* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as rs1275344272, COSV63854672; called by muse, varscan2
- ROS1 | c.6689G>C p.R2230T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV63853286, COSV63854679, COSV63859845; called by muse, varscan2
- RPE65 | c.1333G>C p.D445H | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52015579; called by muse, mutect2, varscan2
- RPGR | c.2495C>G p.S832* (on ENST00000339363 / NM_001367249.1; = p.S627* on NM_000328.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as COSV58834775; called by muse, mutect2, varscan2
- RPH3A | c.1615G>A p.E539K (on ENST00000389385 / NM_001143854.2; = p.E535K on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV66990912; called by muse, mutect2, varscan2
- RPL4 | c.181C>G p.Q61E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); catalogued as rs768431706, COSV57179619; called by muse, mutect2, varscan2
- RPL7L1 | c.341G>T p.R114I | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV59034650; called by muse, mutect2, varscan2
- RPRD2 | c.3544C>T p.R1182C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs764057013, COSV64818585; called by muse, varscan2
- RPRD2 | c.3583C>T p.P1195S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as COSV64819857; called by muse, varscan2
- RPTOR | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.526); catalogued as COSV60808002; called by muse, mutect2, varscan2
- RPUSD2 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.36); PolyPhen benign (0.065); catalogued as rs1335539793, COSV59765445, COSV59765455; called by muse, mutect2, varscan2
- RPUSD3 | c.955C>G p.L319V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV59614241; called by muse, mutect2, varscan2
- RPUSD4 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142091462; called by muse, mutect2, varscan2
- RRP12 | c.2061G>C p.K687N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100213324, COSV59667270; called by muse, mutect2, varscan2
- RRP15 | c.130G>C p.D44H | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV65117824, COSV65118577; called by muse, mutect2, varscan2
- RSF1 | c.3800C>G p.S1267* | Nonsense Mutation (SNP) | VAF 42/51 reads (82%) | catalogued as COSV57838864; called by muse, mutect2, varscan2
- RTL4 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV61206333; called by muse, mutect2, varscan2
- RTN4 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as COSV58267311; called by muse, mutect2, varscan2
- RUNX1T1 | c.1387G>A p.E463K (on ENST00000265814 / NM_001198628.1; = p.E436K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/88 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56145300; called by muse, mutect2, varscan2
- S100A16 | c.246G>C p.L82F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.488); catalogued as COSV64182829; called by muse, mutect2, varscan2
- SAA1 | c.239G>C p.R80T | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV62946155, COSV62946538; called by muse, mutect2, varscan2
- SACS | c.6142G>A p.E2048K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.728); catalogued as COSV66539105; called by muse, mutect2, varscan2
- SAFB2 | c.1584G>C p.K528N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV53042215; called by muse, mutect2, varscan2
- SALL1 | c.3506G>C p.R1169T | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV51756854; called by muse, mutect2, varscan2
- SAMD9 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV101180149, COSV66074870; called by muse, mutect2, varscan2
- SAR1A | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV64698020; called by muse, mutect2, varscan2
- SASS6 | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54927790; called by muse, mutect2, varscan2
- SATB2 | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 34/76 reads (45%) | catalogued as COSV53483000; called by muse, mutect2, varscan2
- SATB2 | c.322C>G p.H108D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53483011; called by muse, mutect2, varscan2
- SCAF4 | c.1343C>G p.S448C | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54586595; called by muse, mutect2, varscan2
- SCG2 | c.208C>A p.H70N | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769298378, COSV100544690; called by muse, mutect2, varscan2
- SCGB1D2 | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV55274341; called by muse, mutect2, varscan2
- SCN10A | c.2258C>G p.S753C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs1319283606, COSV101479454, COSV71861186; called by muse, mutect2
- SDS | c.423C>G p.I141M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV57453332; called by muse, mutect2, varscan2
- SEC16A | c.4636A>G p.R1546G | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51526922; called by muse, mutect2, varscan2
- SEPTIN3 | c.653C>G p.S218C | Missense Mutation (SNP) | VAF 107/139 reads (77%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as COSV52171927; called by muse, mutect2, varscan2
- SERPINA10 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV56228247; called by muse, mutect2, varscan2
- SERPINB9 | c.14C>G p.S5C | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.123); catalogued as COSV66233314, COSV66233440; called by muse, mutect2, varscan2
- SESN3 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.933); catalogued as COSV53584688, COSV99565218; called by muse, mutect2, varscan2
- SGIP1 | c.636G>C p.Q212H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as COSV52767755; called by muse, mutect2
- SGO2 | c.1900G>C p.D634H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs1350260031, COSV63415139; called by muse, mutect2, varscan2
- SGPL1 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV100167285; called by muse, mutect2, varscan2
- SGTA | c.384C>G p.F128L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV55593875; called by muse, mutect2, varscan2
- SH3PXD2B | c.2219C>G p.S740C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.174); catalogued as COSV61126575; called by muse, mutect2, varscan2
- SH3TC2 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60462806; called by muse, mutect2, varscan2
- SHF | c.226C>G p.Q76E | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV52050356; called by muse, mutect2, varscan2
- SHQ1 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as rs199551642, COSV57765174; called by muse, mutect2, varscan2
- SIM2 | c.1508C>A p.S503Y | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV51768407; called by muse, mutect2, varscan2
- SKIV2L | c.838C>G p.Q280E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV64811421; called by muse, mutect2, varscan2
- SLC12A5 | c.1210G>A p.D404N (on ENST00000454036 / NM_001134771.2; = p.D381N on NM_020708.5) | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs776238585, COSV54792870, COSV54793557; called by muse, mutect2, varscan2
- SLC15A2 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV55197603; called by muse, mutect2, varscan2
- SLC15A4 | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as COSV57161310; called by muse, mutect2, varscan2
- SLC16A9 | c.1454C>G p.S485C | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68098875; called by muse, mutect2, varscan2
- SLC22A15 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.045); catalogued as COSV65677886; called by muse, mutect2, varscan2
- SLC22A2 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV65266189; called by muse, mutect2, varscan2
- SLC22A5 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV55372802; called by muse, mutect2, varscan2
- SLC25A12 | c.1525C>G p.L509V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.292); catalogued as COSV55532141, COSV55533153; called by muse, mutect2, varscan2
- SLC25A34 | c.439C>G p.H147D | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV53816854; called by muse, mutect2, varscan2
- SLC25A39 | c.792C>G p.I264M (on ENST00000377095 / NM_001143780.3; = p.I256M on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as rs748101051, COSV56587257; called by muse, mutect2, varscan2
- SLC26A9 | c.2040C>G p.I680M | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV61602437; called by muse, mutect2, varscan2
- SLC35C1 | c.1077G>C p.K359N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as COSV58479342, COSV58479894; called by muse, mutect2, varscan2
- SLC39A1 | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1401558927, COSV57842563; called by muse, mutect2, varscan2
- SLC49A4 | c.643C>T p.L215F | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV53746785; called by muse, mutect2, varscan2
- SLC4A3 | c.2575G>T p.E859* | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | catalogued as COSV56093370; called by muse, varscan2
- SLC4A3 | c.2641G>T p.E881* | Nonsense Mutation (SNP) | VAF 17/29 reads (59%) | catalogued as COSV56093375; called by muse, varscan2
- SLC4A4 | c.1353G>C p.K451N (on ENST00000264485 / NM_001098484.3; = p.K407N on NM_003759.4) | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52623154; called by muse, mutect2, varscan2
- SLC4A4 | c.2619G>A p.V873= (on ENST00000264485 / NM_001098484.3; = p.V829= on NM_003759.4) | Splice Region (SNP) | VAF 50/71 reads (70%) | catalogued as COSV52623162; called by muse, mutect2, varscan2
- SLC9B2 | c.121G>C p.D41H | Missense Mutation (SNP) | VAF 73/138 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV60018946; called by muse, mutect2, varscan2
- SLF2 | c.176C>G p.S59* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as COSV53271460, COSV53273287; called by muse, mutect2, varscan2
- SLITRK4 | c.1312G>C p.E438Q | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62023532, COSV62024204; called by muse, mutect2, varscan2
- SMARCC2 | c.1100C>G p.S367* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as COSV57217897; called by muse, mutect2, varscan2
- SMARCE1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); catalogued as COSV52860919; called by muse, mutect2, varscan2
- SMARCE1 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1430611904, COSV52860937; called by muse, mutect2, varscan2
- SMC3 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV100699887; called by muse, mutect2, varscan2
- SMG1 | c.10912G>A p.D3638N | Missense Mutation (SNP) | VAF 113/265 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67170981; called by muse, mutect2, varscan2
- SMG8 | c.1298G>A p.R433K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56283936; called by muse, mutect2, varscan2
- SMNDC1 | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.229); catalogued as COSV63651748; called by muse, mutect2, varscan2
- SMO | c.859G>C p.D287H | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV50828007; called by muse, mutect2, varscan2
- SNAPC4 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1458587951, COSV53732794; called by muse, mutect2, varscan2
- SNCAIP | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.193); catalogued as COSV54408977; called by muse, mutect2, varscan2
- SNED1 | c.2218C>A p.Q740K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.079); catalogued as COSV60023472; called by muse, mutect2, varscan2
- SNW1 | c.228G>C p.M76I | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV55054200; called by muse, mutect2, varscan2
- SOX15 | c.413G>C p.R138T | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as COSV51468183, COSV51469412; called by muse, mutect2, varscan2
- SP100 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as COSV50978745; called by muse, mutect2, varscan2
- SP6 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV60617393; called by muse, mutect2, varscan2
- SPDL1 | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.853); catalogued as COSV54667948; called by muse, mutect2, varscan2
- SPEF2 | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56796353; called by muse, mutect2, varscan2
- SPOUT1 | c.165G>C p.K55N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.154); catalogued as COSV56913503; called by muse, mutect2
- SPPL2A | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs768668639, COSV55939678; called by muse, mutect2, varscan2
- SRA1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs1302143435, COSV60365354; called by muse, mutect2, varscan2
- SRGN | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54344721; called by muse, mutect2, varscan2
- SSMEM1 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 23/36 reads (64%) | catalogued as COSV52833422; called by muse, mutect2, varscan2
- ST3GAL1 | c.1019G>A p.R340K | Missense Mutation (SNP) | VAF 46/85 reads (54%) | PolyPhen benign (0.277); catalogued as COSV60612609; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 17/48 reads (35%) | PolyPhen probably damaging (0.91); catalogued as COSV60319918; called by muse, mutect2, varscan2
- STIL | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as COSV54549935; called by muse, mutect2, varscan2
- STK31 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV63455740; called by muse, mutect2, varscan2
- STK35 | c.926G>A p.C309Y | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.115); catalogued as COSV55690436; called by muse, mutect2, varscan2
- STRADA | c.238G>C p.E80Q (on ENST00000336174 / NM_001363786.1; = p.E43Q on NM_153335.6) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.673); catalogued as COSV55561977; called by muse, mutect2, varscan2
- STYXL1 | c.469C>G p.Q157E | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs372639771; called by muse, mutect2, varscan2
- SULT1B1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs540095455, COSV100150508, COSV60207513; called by muse, mutect2, varscan2
- SULT4A1 | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs1257352010, COSV50780879; called by muse, mutect2, varscan2
- SYCP1 | c.2714C>T p.S905L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV101050891; called by muse, mutect2, varscan2
- SYP | c.225C>T p.F75= | Splice Region (SNP) | VAF 20/43 reads (47%) | catalogued as COSV54295060; called by muse, mutect2, varscan2
- SYT14 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55053258; called by muse, mutect2, varscan2
- SYT6 | c.958G>C p.D320H (on ENST00000610222 / NM_001366225.1; = p.D235H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65773619; called by muse, mutect2, varscan2
- TANGO2 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as rs764219300, COSV100530030; called by muse, mutect2, varscan2
- TARS3 | c.2150C>G p.S717C | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV100254511; called by muse, mutect2, varscan2
- TBC1D8B | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 107/155 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745566839, COSV52178358; called by muse, mutect2, varscan2
- TBX3 | c.1061C>T p.S354F (on ENST00000257566 / NM_016569.4; = p.S334F on NM_005996.4) | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV57471133; called by muse, mutect2, varscan2
- TCEA2 | c.299C>G p.S100W | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1476778458, COSV58657710; called by muse, mutect2, varscan2
- TCERG1L | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as COSV64049621; called by muse, varscan2
- TDP1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV59643098; called by muse, mutect2, varscan2
- TDRD1 | c.2002C>A p.L668I | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52590215; called by muse, mutect2, varscan2
- TECPR1 | c.2144C>G p.S715C | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV65783274; called by muse, mutect2, varscan2
- TECPR1 | c.1543C>G p.L515V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.036); catalogued as COSV65783281; called by muse, mutect2, varscan2
- TEX10 | c.259C>G p.Q87E | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.05); catalogued as COSV66515224; called by muse, mutect2, varscan2
- TEX13A | c.1229G>C p.*410Sext*? | Nonstop Mutation (SNP) | VAF 29/139 reads (21%) | catalogued as COSV100781156; called by muse, mutect2, varscan2
- TFCP2 | c.551C>G p.S184C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99071318; called by muse, mutect2, varscan2
- TFE3 | c.1026G>C p.L342F | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.477); catalogued as COSV59946812; called by muse, mutect2, varscan2
- THADA | c.3164G>A p.R1055K | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57682634; called by muse, mutect2, varscan2
- THNSL2 | c.1126C>G p.Q376E | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1420699376, COSV59082818; called by muse, mutect2, varscan2
- THSD1 | c.457C>A p.Q153K | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV51628167; called by muse, mutect2, varscan2
- TJP2 | c.155G>C p.R52T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55266223; called by muse, mutect2, varscan2
- TJP2 | c.2521G>C p.D841H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV55266258; called by muse, mutect2, varscan2
- TLE4 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.309); catalogued as COSV54631303; called by muse, mutect2, varscan2
- TLL2 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV63572272; called by muse, mutect2, varscan2
- TMEM141 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV51566956; called by muse, mutect2, varscan2
- TMEM51 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.246); catalogued as rs775821858, COSV101051486, COSV65690951; called by muse, mutect2, varscan2
- TMEM81 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV52704328; called by muse, mutect2, varscan2
- TMPPE | c.1200G>C p.L400F | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV56563394; called by muse, mutect2, varscan2
- TMTC2 | c.474C>G p.H158Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as rs1339788771, COSV58267451; called by muse, mutect2, varscan2
- TNFRSF1B | c.1193C>A p.S398Y | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV66164197; called by muse, mutect2, varscan2
- TNPO1 | c.895G>C p.D299H | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV61521533; called by muse, mutect2, varscan2
- TOP3B | c.1655-1G>C p.X552_splice | Splice Site (SNP) | VAF 14/25 reads (56%) | catalogued as COSV64117182; called by muse, mutect2, varscan2
- TOX2 | c.389C>T p.S130F (on ENST00000358131 / NM_001098798.2; = p.S79F on NM_032883.3) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs755716363, COSV57885799; called by muse, mutect2, varscan2
- TP53BP2 | c.3252G>T p.M1084I (on ENST00000343537 / NM_001031685.3; = p.M955I on NM_005426.2) | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV59068099; called by muse, mutect2, varscan2
- TP73 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs774822513, COSV60700865; called by muse, mutect2, varscan2
- TPP2 | c.1679-1G>A p.X560_splice | Splice Site (SNP) | VAF 9/15 reads (60%) | catalogued as COSV101060240; called by muse, mutect2, varscan2
- TPSG1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as rs1397237003, COSV52354288; called by muse, mutect2
- TRAM1 | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV51597966; called by muse, mutect2, varscan2
- TRIM42 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV53882608, COSV53883905; called by muse, mutect2
- TRIM9 | c.1425C>A p.Y475* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV53616473; called by muse, mutect2, varscan2
- TRIR | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54406828; called by muse, mutect2, varscan2
- TRMT10A | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV56744922, COSV99910861; called by muse, mutect2, varscan2
- TROAP | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV57743922; called by muse, mutect2, varscan2
- TRPC4 | c.2879A>T p.D960V (on ENST00000379705 / NM_016179.4; = p.D965V on NM_003306.3) | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV58998870; called by muse, mutect2, varscan2
- TRPC6 | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as rs1460843912, COSV60254013; called by muse, mutect2, varscan2
- TRPM8 | c.3063C>G p.F1021L | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100223917; called by muse, mutect2
- TSGA10 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0.094); catalogued as COSV61821763; called by muse, mutect2
- TSR1 | c.972G>A p.M324I | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs748274796, COSV52157666; called by muse, mutect2, varscan2
- TTBK1 | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV52490822; called by muse, mutect2, varscan2
- TTC25 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1567928691, COSV66368019; called by muse, mutect2, varscan2
- TTC5 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as rs201731132, COSV51870780, COSV51871980, COSV51872245; called by muse, mutect2, varscan2
- TTI1 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65061529; called by muse, mutect2, varscan2
- TTN | c.96469G>A p.E32157K (on ENST00000591111; = p.E24733K on NM_003319.4) | Missense Mutation (SNP) | VAF 35/91 reads (38%) | PolyPhen possibly damaging (0.819); catalogued as COSV60023183, COSV60292066; called by muse, mutect2, varscan2
- TTN | c.92575C>T p.P30859S (on ENST00000591111; = p.P23435S on NM_003319.4) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | PolyPhen probably damaging (0.998); catalogued as COSV60023223; called by muse, mutect2, varscan2
- TTN | c.92203G>C p.E30735Q (on ENST00000591111; = p.E23311Q on NM_003319.4) | Missense Mutation (SNP) | VAF 24/52 reads (46%) | PolyPhen benign (0.049); catalogued as COSV60023271; called by muse, mutect2, varscan2
- TTN | c.79660G>A p.E26554K (on ENST00000591111; = p.E19130K on NM_003319.4) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | PolyPhen possibly damaging (0.737); catalogued as COSV59926253; called by muse, mutect2, varscan2
- TTN | c.69547G>A p.D23183N (on ENST00000591111; = p.D15759N on NM_003319.4) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | PolyPhen probably damaging (0.964); catalogued as COSV60023380; called by muse, mutect2, varscan2
- TTN | c.37464G>C p.K12488N (on ENST00000591111; = p.K5064N on NM_003319.4) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | PolyPhen probably damaging (0.964); catalogued as COSV60023470; called by muse, mutect2, varscan2
- TTN | c.32362G>C p.E10788Q (on ENST00000591111; = p.E9861Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/34 reads (50%) | PolyPhen benign (0.001); catalogued as rs757633144, COSV60023517; called by muse, mutect2, varscan2
- TUBA3D | c.143C>G p.S48C | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.042); catalogued as COSV58311598; called by muse, mutect2, varscan2
- UBA3 | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.188); catalogued as COSV62740287; called by muse, mutect2, varscan2
- UBAP1 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.055); catalogued as COSV52658678; called by muse, mutect2, varscan2
- UBE2Q2 | c.48C>G p.I16M | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); catalogued as COSV51192867; called by muse, mutect2, varscan2
- UBE3C | c.3223G>C p.E1075Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.401); catalogued as rs1330234039, COSV61952883, COSV61953054; called by muse, mutect2
- UFD1 | c.480C>G p.I160M | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54251219; called by muse, mutect2, varscan2
449 further variants in this file (99 protein-altering or splice-affecting, 315 silent, 35 other) are not listed here.
